Somatic mutation profile of tumor specimen TCGA-AG-A01Y-01A (aliquot TCGA-AG-A01Y-01A-41W-A096-10) from TCGA case TCGA-AG-A01Y, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 49.6 years (18,112 days).
Specimen TCGA-AG-A01Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca197193-04bf-4ecd-970c-67a38eee732a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-A01Y-11A (Solid Tissue Normal), aliquot TCGA-AG-A01Y-11A-11W-A096-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a013f8e-531c-4426-973d-00ae6d6c1ba3

The open-access MAF lists 95 somatic variants for this specimen: 72 protein-altering or splice-affecting, 22 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 22, Splice Region 3, Nonsense Mutation 3, Frame Shift Del 2, Frame Shift Ins 2, Splice Site 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3880C>T p.Q1294* | Nonsense Mutation (SNP) | VAF 80/118 reads (68%) | hotspot (GDC flag); catalogued as rs1554085373, CD058148, CD132712, CM930027, COSV57323524; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 148/267 reads (55%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- AKAP7 | c.192A>C p.E64D | Missense Mutation (SNP) | VAF 156/220 reads (71%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV63504840; called by muse, mutect2, varscan2
- ALPK1 | c.2998G>A p.G1000R | Missense Mutation (SNP) | VAF 63/100 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99453189; called by muse, mutect2, varscan2
- BFSP2 | c.619A>C p.N207H | Missense Mutation (SNP) | VAF 106/329 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV56586742; called by muse, mutect2, varscan2
- BRWD1 | c.2505A>C p.E835D | Missense Mutation (SNP) | VAF 237/416 reads (57%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV100312949; called by muse, mutect2, varscan2
- C4BPA | c.1479G>T p.R493S | Missense Mutation (SNP) | VAF 335/960 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.229); catalogued as COSV65535850; called by muse, mutect2, varscan2
- CACNG7 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 61/160 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs751560841, COSV55816777; called by muse, mutect2, varscan2
- CALCOCO2 | c.95A>G p.Y32C | Missense Mutation (SNP) | VAF 215/751 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as rs769234486, COSV99363660; called by muse, mutect2, varscan2
- CARF | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as rs754703414, COSV100247514; called by muse, mutect2, varscan2
- CCDC81 | c.1558G>T p.E520* (on ENST00000445632 / NM_001156474.2; = p.E430* on NM_021827.4) | Nonsense Mutation (SNP) | VAF 44/197 reads (22%) | catalogued as COSV53577047; called by muse, mutect2, varscan2
- CCSER2 | c.1199C>T p.S400L | Missense Mutation (SNP) | VAF 142/417 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs1159171678, COSV56501668, COSV99825567; called by muse, mutect2, varscan2
- CFHR5 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 203/576 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.173); catalogued as COSV56818144; called by muse, mutect2, varscan2
- CMYA5 | c.977T>C p.I326T | Missense Mutation (SNP) | VAF 124/212 reads (58%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV71404337; called by muse, mutect2, varscan2
- COL25A1 | c.1347T>C p.G449= | Splice Region (SNP) | VAF 63/91 reads (69%) | catalogued as rs770411951, COSV67647278; called by muse, mutect2, varscan2
- DNAH10 | c.2786T>A p.I929N (on ENST00000409039; = p.I868N on NM_207437.3) | Missense Mutation (SNP) | VAF 94/270 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV68989253; called by muse, mutect2, varscan2
- DPF2 | c.1111T>A p.C371S | Missense Mutation (SNP) | VAF 145/303 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99361371; called by muse, mutect2, varscan2
- EIF4A2 | c.1096C>G p.R366G | Missense Mutation (SNP) | VAF 122/315 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99961038; called by muse, mutect2, varscan2
- FAM114A1 | c.1573A>G p.S525G | Missense Mutation (SNP) | VAF 112/386 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV62672154; called by muse, mutect2, varscan2
- FAM135A | c.984C>G p.H328Q (on ENST00000370479 / NM_001351599.1; = p.H311Q on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 197/553 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV52048633, COSV99526912; called by muse, varscan2
- FAM47C | c.886C>T p.R296W | Missense Mutation (SNP) | VAF 77/144 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as rs1415620320, COSV63724383; called by muse, mutect2, varscan2
- GOLGA6A | c.2044C>A p.Q682K | Missense Mutation (SNP) | VAF 37/239 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV99297032; called by muse, mutect2, varscan2
- GPR139 | c.986C>T p.P329L | Missense Mutation (SNP) | VAF 98/274 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs904899563, COSV58501823; called by muse, mutect2, varscan2
- HADHB | c.874C>G p.L292V | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV58545142; called by muse, mutect2, varscan2
- HSD3B1 | c.218G>T p.C73F | Missense Mutation (SNP) | VAF 133/355 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as rs541042731, COSV52489712; called by muse, mutect2, varscan2
- HSPA4 | c.802C>G p.Q268E | Missense Mutation (SNP) | VAF 266/449 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs199586152, COSV59181838; called by muse, mutect2, varscan2
- IL17A | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 300/411 reads (73%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs201890924, COSV60684056; called by muse, mutect2, varscan2
- KCNA2 | c.488G>A p.R163K | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.981); catalogued as COSV100315847; called by muse, mutect2, varscan2
- KRT6A | c.44G>T p.R15L | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs533157590, COSV100416747, COSV100416859; called by muse, mutect2
- LRRC8A | c.2165C>T p.T722M | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.019); catalogued as rs868086143, COSV52184463; called by muse, mutect2, varscan2
- MICB | c.502T>A p.F168I | Missense Mutation (SNP) | VAF 120/154 reads (78%) | SIFT tolerated (0.42); PolyPhen benign (0.44); catalogued as COSV52855823; called by muse, mutect2, varscan2
- MTR | c.2755G>A p.D919N | Missense Mutation (SNP) | VAF 216/419 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.161); catalogued as COSV63964045; called by muse, mutect2, varscan2
- MUC16 | c.31951G>T p.A10651S | Missense Mutation (SNP) | VAF 990/1336 reads (74%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.263); catalogued as rs995033798, COSV101198393, COSV101200948; called by muse, mutect2, varscan2
- MYCBPAP | c.2319C>G p.D773E | Missense Mutation (SNP) | VAF 14/302 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52138030; called by muse, mutect2
- MYO9A | c.1155G>A p.P385= | Splice Region (SNP) | VAF 202/562 reads (36%) | catalogued as rs1264608831, COSV61848302; called by muse, varscan2
- NCDN | c.1231C>T p.R411C | Missense Mutation (SNP) | VAF 93/281 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs746183935, COSV61934904; called by muse, mutect2, varscan2
- NCKAP1L | c.949A>C p.K317Q | Missense Mutation (SNP) | VAF 380/1137 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99514558; called by muse, mutect2, varscan2
- NEK5 | c.902T>C p.I301T | Missense Mutation (SNP) | VAF 206/736 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as COSV62879148; called by muse, mutect2, varscan2
- NEO1 | c.4166-1G>C p.X1389_splice | Splice Site (SNP) | VAF 33/101 reads (33%) | catalogued as COSV99981365; called by muse, mutect2, varscan2
- NPAP1 | c.1462G>A p.V488I | Missense Mutation (SNP) | VAF 88/246 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as rs1176202414, COSV100276390, COSV61508540; called by muse, mutect2, varscan2
- NSUN2 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 105/318 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.665); catalogued as COSV99243003; called by muse, mutect2, varscan2
- OR2A1 | c.223A>T p.N75Y | Missense Mutation (SNP) | VAF 31/214 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV68822706; called by muse, mutect2
- POLR2K | c.49T>C p.Y17H | Missense Mutation (SNP) | VAF 99/230 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs200510163, COSV61958411; called by muse, mutect2, varscan2
- POTEF | c.1077C>A p.D359E | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV62540180; called by muse, mutect2, varscan2
- RALYL | c.366C>T p.G122= | Splice Region (SNP) | VAF 570/1540 reads (37%) | catalogued as rs182622234, COSV72818112; called by muse, mutect2, varscan2
- RASEF | c.522C>G p.I174M | Missense Mutation (SNP) | VAF 48/888 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as COSV100906797, COSV64586464; called by muse, mutect2
- SAA2 | c.86T>G p.F29C | Missense Mutation (SNP) | VAF 112/381 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV56776876; called by muse, mutect2, varscan2
- SEC23A | c.1538T>C p.I513T | Missense Mutation (SNP) | VAF 82/369 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV56971646; called by muse, mutect2, varscan2
- SEMA4B | c.313T>A p.Y105N | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.787); catalogued as COSV60172569; called by muse, mutect2, varscan2
- SETX | c.2626A>G p.I876V | Missense Mutation (SNP) | VAF 59/196 reads (30%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as CD040620, COSV99808923; called by muse, mutect2, varscan2
- SLC17A9 | c.994A>T p.T332S | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.034); catalogued as COSV100947731; called by muse, mutect2, varscan2
- SLCO1C1 | c.752T>C p.V251A | Missense Mutation (SNP) | VAF 354/1003 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56869358; called by muse, mutect2, varscan2
- SORCS2 | c.958C>T p.R320W | Missense Mutation (SNP) | VAF 67/196 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.814); catalogued as rs747884144, COSV61162520; called by muse, mutect2, varscan2
- SPTB | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 107/346 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1245522195, COSV101071986; called by muse, mutect2
- STK32B | c.1075C>T p.R359W | Missense Mutation (SNP) | VAF 89/235 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs761076752, COSV51475544; called by muse, mutect2, varscan2
- STRA6 | c.824C>G p.A275G | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as COSV60584753; called by muse, mutect2, varscan2
- SYCP2 | c.731T>C p.F244S | Missense Mutation (SNP) | VAF 128/510 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100698015; called by muse, varscan2
- TBX3 | c.511A>C p.M171L | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.749); catalogued as rs905399897, COSV57469706; called by muse, mutect2, varscan2
- TMEM43 | c.944G>C p.G315A | Missense Mutation (SNP) | VAF 76/214 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1175798316, COSV100044248; called by muse, mutect2, varscan2
- TNKS2 | c.2732A>C p.E911A | Missense Mutation (SNP) | VAF 89/317 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as COSV65414899; called by muse, mutect2, varscan2
- TTN | c.24320A>G p.Q8107R (on ENST00000591111; = p.Q7180R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 105/275 reads (38%) | PolyPhen benign (0.007); catalogued as COSV100597130, COSV59991303; called by muse, mutect2, varscan2
- UBB | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 34/49 reads (69%) | SIFT tolerated (0.07); PolyPhen benign (0.198); catalogued as COSV56218319; called by muse, mutect2, varscan2
- UBR4 | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 77/130 reads (59%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.959); catalogued as rs776684278, COSV100920318; called by muse, mutect2, varscan2
- VWA8 | c.551A>G p.N184S | Missense Mutation (SNP) | VAF 151/290 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754524183, COSV99863641; called by muse, mutect2, varscan2
- ZNF385B | c.617C>T p.T206M | Missense Mutation (SNP) | VAF 214/730 reads (29%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.927); catalogued as rs762051657, COSV61175899; called by muse, mutect2, varscan2
- ZNF518A | c.4204G>T p.D1402Y | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV100283365; called by muse, mutect2, varscan2
- ZNF622 | c.786C>A p.S262R | Missense Mutation (SNP) | VAF 209/580 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.145); catalogued as COSV58073633; called by muse, mutect2, varscan2
- ADAMTS6 | c.2280dup p.S761Ifs*2 | Frame Shift Ins (INS) | VAF 69/156 reads (44%) | called by mutect2, pindel, varscan2
- COL24A1 | c.2551del p.I851Lfs*15 | Frame Shift Del (DEL) | VAF 78/279 reads (28%) | called by mutect2, pindel, varscan2
- RAB6D | c.152dup p.L51Ffs*27 | Frame Shift Ins (INS) | VAF 10/27 reads (37%) | called by mutect2, varscan2
- RHOT1 | c.82_96+4del p.X28_splice | Splice Site (DEL) | VAF 81/442 reads (18%) | called by mutect2, pindel
- ZNF615 | c.2076del p.K692Nfs*51 | Frame Shift Del (DEL) | VAF 182/581 reads (31%) | called by mutect2, pindel, varscan2
- AGT | c.1101C>T p.N367= | Silent (SNP) | VAF 42/138 reads (30%) | catalogued as rs1201671004, COSV64184012; called by muse, mutect2, varscan2
- AIDA | c.697T>C p.L233= | Silent (SNP) | VAF 72/224 reads (32%) | catalogued as COSV60663209; called by muse, mutect2, varscan2
- CBX4 | c.555C>T p.C185= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs1303695302, COSV53964623; called by muse, mutect2
- CELSR2 | c.8607C>T p.S2869= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs552633270, COSV54768029; called by muse, mutect2, varscan2
- CS | c.957T>C p.V319= | Silent (SNP) | VAF 66/160 reads (41%) | catalogued as COSV57524002; called by muse, mutect2, varscan2
- DIS3 | c.2253T>C p.A751= | Silent (SNP) | VAF 107/394 reads (27%) | catalogued as COSV66705777; called by muse, mutect2, varscan2
- DPEP1 | c.477G>A p.L159= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as rs976926264, COSV99878330; called by muse, varscan2
- KCNA3 | c.642C>T p.R214= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs1269316794, COSV63901113; called by muse, varscan2
- KCNB2 | c.1113A>G p.S371= | Silent (SNP) | VAF 63/145 reads (43%) | catalogued as COSV73049228; called by muse, mutect2, varscan2
- KIF4B | c.2460T>C p.I820= | Silent (SNP) | VAF 55/102 reads (54%) | catalogued as COSV70528200; called by muse, mutect2, varscan2
- LBX1 | c.105G>A p.P35= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV64621518; called by muse, mutect2, varscan2
- MAN2B2 | c.1830G>A p.T610= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as rs540141303, COSV53451060; called by muse, mutect2, varscan2
- MYBL1 | c.945C>T p.D315= | Silent (SNP) | VAF 228/563 reads (40%) | catalogued as rs565495156, COSV72918746; called by muse, mutect2, varscan2
- PCDHGA12 | c.261G>A p.A87= | Silent (SNP) | VAF 19/27 reads (70%) | catalogued as rs941765907, COSV99338389; called by muse, mutect2, varscan2
- PSMC4 | c.564C>T p.F188= | Silent (SNP) | VAF 20/119 reads (17%) | catalogued as rs201936053, COSV50094349, COSV99338316; called by muse, mutect2, varscan2
- SELENBP1 | c.1332G>A p.V444= | Silent (SNP) | VAF 129/351 reads (37%) | catalogued as COSV64373101; called by muse, mutect2, varscan2
- SRRM4 | c.873G>C p.T291= | Silent (SNP) | VAF 41/102 reads (40%) | catalogued as COSV57410251; called by muse, mutect2, varscan2
- SVOPL | c.1056C>T p.I352= (on ENST00000419765; = p.I200= on NM_174959.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 57/124 reads (46%) | catalogued as rs374157361; called by muse, mutect2, varscan2
- SYDE1 | c.940C>A p.R314= | Silent (SNP) | VAF 8/11 reads (73%) | catalogued as COSV54618274; called by muse, mutect2, varscan2
- SYNJ2 | c.2244G>A p.K748= | Silent (SNP) | VAF 28/270 reads (10%) | catalogued as COSV62895907; called by muse, mutect2
- TMEM199 | c.507A>G p.Q169= | Silent (SNP) | VAF 12/124 reads (10%) | catalogued as rs762676194, COSV99134707; called by muse, mutect2
- UGT1A4 | c.645C>G p.L215= | Silent (SNP) | VAF 111/323 reads (34%) | catalogued as rs1204222582, COSV59383804; called by muse, mutect2, varscan2
- WNK2 | chr9:93319152 G>A | 3'Flank (SNP) | VAF 46/128 reads (36%) | catalogued as rs1037768891, COSV52933548; called by muse, mutect2, varscan2
